Surgical pathology report (de-identified scan), TCGA case TCGA-IA-A83S, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site Cleveland Clinic, specimen TCGA-IA-A83S-01A (Primary Tumor).

[page 1 of 3]
Results

SURGICAL PATHOLOGY

Patient Info

Patient Name

Sex

DOB

Results

Specimen #:

Physician:

FINAL DIAGNOSIS

LEFT KIDNEY, PARTIAL NEPHRECTOMY - RENAL CELL CARCINOMA, PAPILLARY TYPE
(3.8 CM IN GREATEST DIMENSION), FURHMAN GRADE II/IV.
-THE TUMOR INVADES INTO THE RENAL CAPSULE.
- VASCULAR INVASION IS NOT IDENTIFIED.
- SOFT TISSUE AND PARENCHYMAL MARGINS OF RESECTION ARE NEGATIVE.

Electronic Signature

SPECIMEN SUBMITTED

A: LEFT PARTIAL NEPHRECTOMY

CLINICAL DATA

LEFT RENAL MASS

ICD-O-3
Carcinoma, papillary renal cell
8260/3
Site @ Kidney NOS
C64.9
Jr 10/17/13

GROSS DESCRIPTION

A. Received fresh is a partial nephrectomy specimen measuring 8.5 x 6 x 4.5 cm and weighing 63 grams. The parenchymal margin of resection is inked with black ink, as well as the soft tissue (adipose tissue) line of resection. Multiple cross sections reveal a round, soft, red-brown lesion measuring 3.8 x 3 x 3.5 cm. No foci of necrosis are grossly identified. This lesion is located 0.9 cm away from the closest parenchymal margin of resection and is bulging through the capsule but is not invading into the adjacent adipose tissue. Representative sections are submitted as follows in formalin: #1 parenchymal margin; #2 soft tissue margin; #3 & #4 representative section of the mass.

Patient ID #:

DOB:

Date of Report:

Date of Procedure:

Date of Receipt:

Submitted by:

Location:

Lab and Collection

SURGICAL PATHOLOGY on

[page 2 of 3]
Result History

SURGICAL PATHOLOGY ([REDACTED]) on [REDACTED]

Result Information

Result Date and Time

Status
Final result

Provider Status
Ordered

Status:

This result is currently not released to

[Display Full Result Report](#)

[Display Order Report](#)

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Kidney renal papillary cell carcinoma - carcinoma)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Renal cell carcinoma

Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

papillary type

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

confirmation of clarification of KIRP Type II provided in discrepancy note

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 46824ca1-07cc-43f2-8d45-32c65033bae5 (TCGA-IA-A83S.8B8301E6-D39D-43AA-A7E7-83425DFD0E74.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).